TCGA case TCGA-W5-AA39 — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/32e9558c-946b-4288-91e1-504e47c308ac

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Dead; Days to death: 170 days.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 81.0 years (29,594 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 170 days; Disease response: With Tumor.
- ECOG performance status: 1.

Molecular and laboratory tests
- CA19-9: 57 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 55.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.2 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 2.7 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Platelets 350 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Creatinine 1.1 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.3].
- Albumin 3.5 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 176 cm; BMI: 25.8.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Cervical Cancer.
- Relatives with cancer history count: 2.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA39-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-W5-AA39-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-W5-AA39-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W5-AA39-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Lobectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 170 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 170 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 170 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W5-AA39-01A-11D-A416-01): tumor purity 0.87, ploidy 2.18, whole-genome doublings 0.
